Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE8-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organs: Liver (10.0 x 10.0 x 3.3 cm, 114.0 gm, 6.5 x 6.0 x 1.8 cm and 38.0 gm)

Lesion: A well-defined mass (1.8 x 1.8 x 2.5 cm)

Cut surface: Yellowish tan, and granular without necrosis

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 1.8 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Representative sections submitted

Gross photo: Present

Blocks

TB, T1-3, tumor mass x 4

NB, L, A1-2, liver parenchyma x 4

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: No

Septum formation: Yes

Surgical resection margin invasion: No, safety margin (1.8 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

NOT reported. Gross:

ICD.O-3

Carcinoma, hepatocellular NOS

Site Liver C22.0

8170/3

yo 0/20/14

[page 2 of 2]
Large intestine, ascending colon, ectomy, tubular adenoma, low grade, dysplasia

Large intestine, rectum, dissection, adenocarcinoma, moderately differentiated, arising in,
tubulovillous adenoma

liver,ectomy,Hepatocellular carcinoma, moderately differentiated ,cirrhosis

T56000, P10, M81703, moderately differentiated, M49500

gallbladder,ectomy,chronic cholecystitis

T57000, P10, M43005

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated

Cirrhosis, micronodular

Gallbladder, cholecystectomy:

Chronic cholecystitis

Suggestion :

Source: NCI Genomic Data Commons file f84dc2c7-e807-43f4-9519-63d8d85b34ca (TCGA-DD-AAE8.B94DC39D-E27E-488E-87F3-C1EB76445321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).